Surgical pathology report (de-identified scan), TCGA case TCGA-MK-A84Z, project TCGA-THCA (Thyroid Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MK-A84Z-01A (Primary Tumor).

[page 1 of 3]
---- SURGICAL PATHOLOGY ----

MEDICAL RECORD |

SURGICAL PATHOLOGY

PATHOLOGY REPORT

Accession No.

Submitted by:

Date obtained:

Specimen (Received

:

RIGHT THYROID LOBE STITCH MARK RIGHT SUPERIOR

*** SUPPLEMENTARY REPORT HAS BEEN ADDED ***

*** REFER TO BOTTOM OF REPORT ***

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

right thyroid nodule

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

right thyroid nodule

Surgeon/physician:

Attending Surgeon:

PATHOLOGY REPORT

Accession No.

Pathology Resident:

GROSS DESCRIPTION:

The specimen consists of a 28 grams, 6.5 x 5.2 x 1.8 cm right thyroid lobe. The specimen is surgically oriented by a stitch demarcating the superior lobe. The specimen is inked blue on the anterior/superficial surface, and black on the posterior/deep surface. The specimen is serially sectioned from inferior to superior tip into eleven slices. Serial sectioning reveals a 1.5 x 2.2 x 5.0 cm tan-white partly cystic nodule surrounded by a thin capsule. The adjacent thyroid tissue is red-brown and spongy. The specimen is submitted entirely as follows: 1-11- entire thyroid nodule submitted from inferior to superior; 12-20- associated grossly normal thyroid, submitted entirely.

MICROSCOPIC EXAM
DIAGNOSIS

THYROID, RIGHT, PARTIAL THYROIDECTOMY:
- SEE COMMENT

ICD-O-3
Papillary Carcinoma, follicular variant
834013

Site Thyroid NOS
C73.9

JW 11/29/13

[page 2 of 3]
Comment: The specimen is pending consultation. An addendum will follow.

SUPPLEMENTARY REPORT(S):

Supplementary Report Date:

*** SUPPLEMENTARY REPORT HAS BEEN ADDED/MODIFIED ***

(Added/Last released:

Signed by

ADDENDUM DIAGNOSIS

Thyroid, right, partial thyroidectomy:

- FOLLICULAR VARIANT OF PAPILLARY THYROID CARCINOMA
ARISING IN A BENIGN FOLLICULAR NODULE (SEE COMMENT
AND CANCER SUMMARY) *Per FSE, follicular variant = 100% BCR.*

Comment: Slide 16 shows a small isolated focus of follicular variant of papillary carcinoma.

The case was submitted in consultation to
notified at

Pathology Cancer Case Summary

Based on AJCC/UICC TNM, 7th edition

- Procedure: Thyroid lobectomy, right
- Received: In formalin
- Specimen Integrity: Intact
- Specimen Size: 6.5 x 5.2 x 1.8 cm
- Specimen Weight: 28 g
- Tumor Focality: Multifocal
- Dominant Tumor:
- Tumor Size: 1.5 x 2.2 x 5.0
- Histologic Type: Papillary carcinoma, Follicular variant
- Architecture: Follicular
- Cytomorphology: Classical
- Histologic Grade: G1: Well differentiated
- Margins: Margins uninvolved by carcinoma
- Tumor Capsule: Totally encapsulated
- Lymph-Vascular Invasion: Not identified
- Second Tumor:
- Tumor Size: 1 mm
- Histologic Type: Papillary carcinoma, Follicular variant
- Architecture: Follicular
- Cytomorphology: Classical
- Histologic Grade: G1: Well differentiated
- Margins: Margins uninvolved by carcinoma
- Tumor Capsule: Totally encapsulated
- Lymph-Vascular Invasion: Not identified
- Pathologic Staging (pTNM): pT3, pNx, pMx
- Additional Pathologic Findings

[page 3 of 3]
- Follicular nodule
- Hurtle cell hyperplasia

Source: NCI Genomic Data Commons file 9b5f1fe0-3c7e-4bbe-9dfd-9ed2bd04e452 (TCGA-MK-A84Z.A0C1F12C-4035-4651-B43D-EA3708DC8FF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).